CCDI case PBBKXJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/34dac78d-e1ce-4703-931d-b3d174d24bf2

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.8 years (2,495 days).

Biospecimens (3 samples)
- Sample 0DB97L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DB97X: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DB983: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
